Somatic mutation profile of tumor specimen TCGA-2Z-A9JG-01A (aliquot TCGA-2Z-A9JG-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JG, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.2 years (23,458 days).
Specimen TCGA-2Z-A9JG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b7a2275-aa13-4781-8806-aa78f7bf4684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JG-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JG-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e23f7390-f9b6-476a-838c-80dd3d9db2da

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Frame Shift Del 10, Intron 3, Nonsense Mutation 3, 5'UTR 2, Nonstop Mutation 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS6 | c.961T>G p.L321V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV100782231; called by muse, mutect2, varscan2
- AOC2 | c.2200C>T p.P734S (on ENST00000253799 / NM_009590.4; = p.P707S on NM_001158.5) | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99520006; called by muse, mutect2, varscan2
- ARHGAP11A | c.1517T>C p.L506S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100853178; called by muse, mutect2, varscan2
- ARID5B | c.1190A>G p.H397R | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99689184; called by muse, mutect2, varscan2
- ATP1A2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs181618883, COSV63404142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUD31 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 87/143 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99769015; called by muse, mutect2, varscan2
- CBFA2T2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 135/286 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV100656189; called by muse, mutect2, varscan2
- CDYL | c.619A>G p.T207A (on ENST00000328908 / NM_001368125.1; = p.T153A on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100188867; called by muse, mutect2, varscan2
- CEP126 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV99680732; called by muse, mutect2, varscan2
- CEP95 | c.763del p.E255Sfs*24 | Frame Shift Del (DEL) | VAF 70/156 reads (45%) | catalogued as COSV73609556; called by mutect2, pindel, varscan2
- CSNK1E | c.921G>C p.E307D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100724993; called by muse, mutect2, varscan2
- CUX2 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as rs1323492109, COSV99918860; called by muse, mutect2, varscan2
- DDN | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100304933; called by muse, mutect2, varscan2
- DPYSL4 | c.628A>T p.K210* | Nonsense Mutation (SNP) | VAF 24/39 reads (62%) | catalogued as COSV100633861; called by muse, mutect2, varscan2
- FAM102A | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs764272778, COSV100905360; called by muse, mutect2, varscan2
- FRG2B | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV101423501; called by muse, mutect2, varscan2
- FRY | c.5657T>C p.L1886S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100968881; called by muse, mutect2, varscan2
- FZD2 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV100190266; called by muse, mutect2, varscan2
- GLRA1 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99199451; called by muse, mutect2, varscan2
- GTF3C1 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs778526776, COSV100649049; called by muse, mutect2, varscan2
- HOXD1 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 87/146 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100514112; called by muse, mutect2, varscan2
- IGHV2-5 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 127/307 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs371173800; called by muse, mutect2, varscan2
- IRX6 | c.18T>G p.F6L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99306244; called by muse, mutect2, varscan2
- JADE3 | c.2204del p.K735Sfs*6 | Frame Shift Del (DEL) | VAF 34/44 reads (77%) | catalogued as COSV54465810; called by mutect2, pindel*, varscan2
- KARS1 | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1172517003, COSV100093825; called by muse, mutect2, varscan2
- KCNQ1 | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV99325987; called by muse, mutect2, varscan2
- KLHL42 | c.1253T>A p.V418E | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101179705; called by muse, mutect2, varscan2
- KRTAP27-1 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776229826, COSV101239687; called by muse, mutect2, varscan2
- LEPR | c.2621A>G p.D874G | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV100756374; called by muse, mutect2, varscan2
- MBLAC1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99498771; called by muse, mutect2, varscan2
- MEX3B | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV100313894; called by muse, mutect2, varscan2
- MSI1 | c.506T>A p.I169N | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99981396; called by muse, mutect2, varscan2
- MYH14 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV51833650; called by muse, mutect2, varscan2
- MYL12A | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV99470117; called by muse, mutect2, varscan2
- NEDD9 | c.2135A>G p.Y712C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as rs758864980, COSV101060780; called by muse, mutect2, varscan2
- OR4A5 | c.872T>G p.M291R | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.845); catalogued as COSV100156987; called by muse, mutect2, varscan2
- PAN3 | c.999A>G p.P333= | Splice Region (SNP) | VAF 25/55 reads (45%) | catalogued as COSV101111115; called by muse, mutect2, varscan2
- PARD6B | c.230A>C p.N77T | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100859879; called by muse, mutect2, varscan2
- PAX8 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99639214; called by muse, mutect2, varscan2
- PCNX3 | c.3649C>G p.L1217V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV100856088, COSV63137992; called by muse, mutect2, varscan2
- POLR1A | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771151845, COSV99807222; called by muse, mutect2, varscan2
- POU5F2 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV101232681; called by muse, mutect2, varscan2
- PRCC | c.1362A>C p.K454N | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99618499; called by muse, mutect2, varscan2
- PTPRT | c.3989G>A p.R1330H | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs528913627, COSV61974234; called by muse, mutect2, varscan2
- RANBP1 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV100082078; called by muse, mutect2, varscan2
- SAV1 | c.660T>A p.H220Q | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100220665; called by muse, mutect2, varscan2
- SELENOF | c.498A>T p.*166Yext*? | Nonstop Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100085862; called by muse, mutect2, varscan2
- SMAGP | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 107/189 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV101199380; called by muse, mutect2, varscan2
- SOAT1 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV100858894; called by muse, mutect2, varscan2
- STKLD1 | c.298T>G p.S100A | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as COSV100911918; called by muse, mutect2, varscan2
- SYNE1 | c.23537C>T p.A7846V (on ENST00000367255 / NM_182961.4; = p.A7775V on NM_033071.3) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99555812; called by muse, mutect2, varscan2
- TAS1R3 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100229312; called by muse, mutect2, varscan2
- TDG | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99904070; called by muse, mutect2, varscan2
- TLN1 | c.2783C>A p.A928D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100147409; called by muse, mutect2, varscan2
- UBE2D2 | c.356T>A p.L119* | Nonsense Mutation (SNP) | VAF 46/97 reads (47%) | catalogued as COSV99551309; called by muse, mutect2, varscan2
- UBE2K | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV99787082; called by muse, mutect2, varscan2
- ZNF565 | c.758A>T p.H253L (on ENST00000355114; = p.H213L on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100411814; called by muse, mutect2, varscan2
- AHCTF1 | c.226_226+10del p.X76_splice (on ENST00000366508; = p.X50_splice on NM_015446.5) | Splice Site (DEL) | VAF 37/147 reads (25%) | called by mutect2, pindel, varscan2
- CEP290 | c.789dup p.V264Cfs*6 | Frame Shift Ins (INS) | VAF 30/156 reads (19%) | called by mutect2, pindel*, varscan2*
- DNAH1 | c.4201del p.V1401Wfs*5 | Frame Shift Del (DEL) | VAF 55/140 reads (39%) | called by mutect2, pindel, varscan2
- GGH | c.531del p.P178Lfs*8 | Frame Shift Del (DEL) | VAF 55/241 reads (23%) | called by mutect2, pindel, varscan2
- LIAS | c.299+1del | Frame Shift Del (DEL) | VAF 36/61 reads (59%) | called by mutect2, pindel, varscan2
- PHF3 | c.4144del p.S1382Vfs*3 | Frame Shift Del (DEL) | VAF 72/199 reads (36%) | called by mutect2, pindel, varscan2
- ROCK1 | c.1299_1300del p.Y433* | Nonsense Mutation (DEL) | VAF 8/22 reads (36%) | called by pindel, varscan2
- SLC6A3 | c.14A>T p.K5I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2
- TMPRSS7 | c.2444_2445del p.G815Efs*22 (on ENST00000452346; = p.G689Efs*22 on NM_001042575.2) | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | called by mutect2, pindel*, varscan2
- TPR | c.6518del p.P2173Hfs*19 | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | called by mutect2, pindel, varscan2
- USH1G | c.75del p.N26Mfs*8 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | called by mutect2, pindel*, varscan2
- ZNF540 | c.429_430del p.K143Nfs*4 | Frame Shift Del (DEL) | VAF 50/147 reads (34%) | called by mutect2, pindel, varscan2
- CAPN7 | c.1878A>G p.P626= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs1279050165, COSV99512602; called by muse, mutect2, varscan2
- CTNNA1 | c.258C>A p.L86= | Silent (SNP) | VAF 88/163 reads (54%) | catalogued as COSV100242283, COSV57080002; called by muse, mutect2, varscan2
- DESI2 | c.72T>A p.I24= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99798006; called by muse, mutect2, varscan2
- DUS3L | c.1557T>A p.I519= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100287974; called by muse, mutect2, varscan2
- EPHA5 | c.159C>A p.L53= | Silent (SNP) | VAF 118/181 reads (65%) | catalogued as COSV99896915; called by muse, mutect2
- ESYT2 | c.2667C>T p.G889= (on ENST00000613624; = p.G813= on NM_020728.3) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1159321989, COSV99276276; called by muse, mutect2, varscan2
- FAT4 | c.2142T>C p.T714= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV101272129; called by muse, mutect2, varscan2
- IRF2BP2 | c.1578G>C p.S526= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs1335477095, COSV100784261; called by muse, mutect2, varscan2
- KLHDC10 | c.513T>C p.G171= | Silent (SNP) | VAF 48/156 reads (31%) | catalogued as COSV100110888; called by muse, mutect2, varscan2
- KMT2A | c.10536T>A p.P3512= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as rs782373846, COSV100628161; called by muse, mutect2, varscan2
- LAMA1 | c.2817T>C p.Y939= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as CD147518, COSV101055371; called by muse, mutect2, varscan2
- MOV10L1 | c.2965A>C p.R989= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV99432934; called by muse, mutect2, varscan2
- RB1CC1 | c.189T>C p.S63= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99207449; called by muse, mutect2, varscan2
- SMG7 | c.471C>T p.H157= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100750119; called by muse, mutect2, varscan2
- TMEM88 | c.432C>G p.A144= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs936323451, COSV99640863; called by muse, mutect2, varscan2
- TP53BP1 | c.789T>G p.P263= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV55500534, COSV99779976; called by muse, mutect2, varscan2
- VWF | c.6423C>A p.V2141= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV99778293; called by muse, mutect2, varscan2
- ZNF629 | c.615C>T p.P205= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as COSV52698956; called by muse, mutect2, varscan2
- EPDR1 | c.-47C>A | 5'UTR (SNP) | VAF 46/148 reads (31%) | catalogued as rs1431755827, COSV99554284; called by muse, mutect2, varscan2
- FAM114A1 | c.-158+238A>T | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs1309447183; called by muse, varscan2
- RBPMS2 | c.88-10852G>A | Intron (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100264796; called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+597G>A | Intron (SNP) | VAF 17/56 reads (30%) | catalogued as COSV101530513; called by muse, mutect2, varscan2
- VPS11 | c.-657_-655del | 5'UTR (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
